Somatic mutation profile of tumor specimen TCGA-QT-A5XN-01A (aliquot TCGA-QT-A5XN-01A-11D-A35D-08) from TCGA case TCGA-QT-A5XN, project TCGA-PCPG (Pheochromocytoma and Paraganglioma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Pheochromocytoma, malignant; Tissue or organ of origin: Adrenal gland, NOS; Age at diagnosis: 51.5 years (18,812 days).
Specimen TCGA-QT-A5XN-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 111e13eb-c689-43ec-9ea0-cfb2a65ee6ae.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-QT-A5XN-10A (Blood Derived Normal), aliquot TCGA-QT-A5XN-10A-01D-A35B-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/23b5c416-5150-4248-a4f5-b9488c77228b

The open-access MAF lists 15 somatic variants for this specimen: 7 protein-altering or splice-affecting, 6 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 6, Silent 6, Intron 1, 5'UTR 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BOD1L1 | c.6847C>G p.P2283A | Missense Mutation (SNP) | VAF 16/30 reads (53%) | SIFT tolerated (0.2); PolyPhen benign (0.079); called by muse, varscan2
- KLHDC3 | c.1076A>G p.D359G | Missense Mutation (SNP) | VAF 78/168 reads (46%) | SIFT tolerated (0.07); PolyPhen benign (0.101); called by muse, mutect2, varscan2
- MATR3 | c.1075C>T p.P359S | Missense Mutation (SNP) | VAF 28/111 reads (25%) | SIFT tolerated (0.22); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- NBN | c.774del p.E259Nfs*17 | Frame Shift Del (DEL) | VAF 26/108 reads (24%) | called by mutect2, pindel, varscan2
- SLC26A9 | c.2359A>C p.T787P | Missense Mutation (SNP) | VAF 41/152 reads (27%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.855); called by muse, mutect2, varscan2
- USP34 | c.5840T>C p.L1947S | Missense Mutation (SNP) | VAF 29/62 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ZACN | c.228C>G p.I76M | Missense Mutation (SNP) | VAF 5/57 reads (9%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); called by muse, mutect2
- ESX1 | c.816C>A p.P272= | Silent (SNP) | VAF 58/122 reads (48%) | called by muse, mutect2, varscan2
- MERTK | c.228A>T p.G76= | Silent (SNP) | VAF 18/34 reads (53%) | called by muse, mutect2, varscan2
- MYOM2 | c.2325G>A p.L775= | Silent (SNP) | VAF 18/43 reads (42%) | catalogued as rs1273254772; called by muse, mutect2, varscan2
- NLRP4 | c.504G>A p.L168= | Silent (SNP) | VAF 29/89 reads (33%) | catalogued as rs1489038353; called by muse, mutect2, varscan2
- OTOP3 | c.291C>T p.A97= | Silent (SNP) | VAF 25/63 reads (40%) | catalogued as rs774954844; called by muse, mutect2, varscan2
- SCN5A | c.2151G>A p.P717= | Silent (SNP) | VAF 32/45 reads (71%) | catalogued as rs191840835, COSV61133977; ClinVar: benign / likely benign / uncertain significance; called by muse, mutect2, varscan2
- OBSCN | c.18662-2801G>A | Intron (SNP) | VAF 14/23 reads (61%) | catalogued as rs760210504; called by muse, mutect2, varscan2
- REPIN1 | c.-295T>A | 5'UTR (SNP) | VAF 33/56 reads (59%) | called by muse, mutect2, varscan2
